TARGET case TARGET-40-PASNCK — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dc65582e-c7e2-5ab5-95f6-243ea2efd8f4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 14 years; Vital status: Dead; Days to death: 953 days (2.6 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 14.2 years (5,195 days); Year of diagnosis: 2009; Metastasis at diagnosis: No Metastasis; Days to last follow up: 953 days (2.6 years).
   Treatment given: Protocol identifier: AOST0331.

Follow-up (3 entries)
- Days to follow up: 455 days (1.2 years); Days to first event: 455 days (1.2 years); First event: Second Malignant Neoplasm.
- Days to follow up: 836 days (2.3 years); Progression or recurrence: Yes; Days to progression: 836 days (2.3 years).
- Days to follow up: 953 days (2.6 years); Year of follow up: 2011.

Biospecimens (2 samples)
- Sample TARGET-40-PASNCK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PASNCK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PASNCK-01A:
- Specimen Type: Frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 97
- % Non Tumor Nuclei: Top from Biopsy: 3
- % Cellular Tumor: Top from Biopsy: 65
- % Normal: Top from Biopsy: 0
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 35
- % Tumor Nuclei: Bottom from Biopsy: 98
- % Non Tumor Nuclei: Bottom from Biopsy: 2
- % Cellular Tumor: Bottom from Biopsy: 75
- % Normal: Bottom from Biopsy: 0
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 25
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 953
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Specific tumor region: Distal
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Site of initial relapse: Non-bone, non-lung
- Time to first relapse in days: 836
- Histologic response: Stage 1/2 (0-90 % necrosis)
